Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A91X, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A91X-01A (Primary Tumor).

[page 1 of 2]
Collect date:

ICD-O-3
Adenocarcinoma, intestinal
8144/3
Site Gastric antrum C16.3
7/23/18/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

“Stomach:

Adenocarcinoma with the following features:

Site: antrum

Histologic pattern:

NOS (not otherwise specified)

Histologic grade: III, poorly differentiated

Lauren classification: intestinal type

Largest tumor size: 5.5 cm.

Ulceration: present

Local invasion:

Muscularis propria

Tumor invasion type

Infiltrative

Inflammatory response

Mild

Tumor implant in perivisceral fat

Not observed

Proximal margin

Uninvolved by neoplasia

Distal margin

Uninvolved by neoplasia

Neural invasion

Present

Lymphatic invasion

Present

Blood vessel invasion

Doubtful

Greater omentum

Uninvolved by neoplasia

Other features: moderate chronic gastritis with focal intestinal metaplasia in adjacent mucosa

Lymph nodes:

Involved by neoplasia: 14 of 34 (14/34)

Capsular invasion: not observed

Lymph node clusters: not observed

Soft tissue tumor implant: not observed

Report of examined lymph nodes according to standardization, JGCA-1998:

[page 2 of 2]
F- Chain 1 – right paracardic: 2/5
G- Chain 2 – left paracardic: 0/2
H- Chain 3 – lesser curvature: 4/7
K – Chain 4d – right gastroepiploic vessels: 0/1
M – Chain 6 – infrapiloric: 3/5
O- Chain 8a – anterior hepatic artery (antero-superior group): 1/3
Q- Chain 9 – celiac trunk: 4/10
S- Chain 11p – proximal splenic artery: 0/1

Esophageal margin:
Uninvolved by neoplasia.

HOPAA Discrepancy		☒

Source: NCI Genomic Data Commons file fdd8fc51-7c98-4ed7-ba67-1a4fc010b8af (TCGA-VQ-A91X.A426706B-59EC-4897-9C55-924D80E3A910.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).